Gene-level copy-number profile of tumor specimen C3N-01071-03 from CPTAC case C3N-01071, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 48.8 years (17,831 days).
Specimen C3N-01071-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e8d6b3bf-bc86-4983-8b8b-648a7ebc99a0.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-01071-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,712 have no estimate.
https://portal.gdc.cancer.gov/files/cc552db4-068e-43e7-80da-a22a96c7e6c9

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 513; copy number 1: 4,578; copy number 2: 40,454; copy number 3: 11,757; copy number 4: 1,282; copy number 5: 303; copy number 6: 24.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 327 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:149,928,651–150,518,032, 21 genes, copy number 5: MTMR11, OTUD7B, AC244033.2, AC244033.1, VPS45, PLEKHO1, RN7SL480P, ANP32E, RNU2-17P, AC242988.1, CA14, APH1A, C1orf54, CIART, MRPS21, PRPF3, RPRD2, TARS2, MIR6878, ECM1, FALEC.
- chr13:67,790,407–70,924,455, 24 genes, copy number 6: BCRP9, NPM1P22, OR7E111P, OR7E33P, ELL2P3, HNRNPA1P18, RPL37P21, RPS3AP52, RPL12P34, RN7SL761P, LINC00550, LINC02342, ZDHHC20P4, SNRPFP3, LINC00383, SRSF1P1, KLHL1, RNY3P10, PSMC1P13, ATXN8OS, AL160391.1, RNU6-54P, AL445264.1, MTCL1P1.
- chr13:74,434,538–92,873,682, 165 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr14:18,333,726–18,343,144, 2 genes, copy number 5: CR383658.1, RNU6-458P.
- chr14:89,412,312–89,954,659, 1 gene, copy number 5 (within-gene range 3–5): AL137230.2.
- chr14:89,576,216–92,106,621, 54 genes, copy number 5 (within-gene range 3–5): FOXN3-AS2, RN7SKP107, AL137230.1, Y_RNA, RN7SKP255, CHORDC2P, EFCAB11, RAB42P1, TDP1, KCNK13, GLRXP2, Y_RNA, PSMC1, NRDE2, AL161662.1, RPL21P11, AL512791.2, CALM1, AL512791.1, LINC02317, LINC00642, AL096869.3, TTC7B, AL096869.1, AL096869.2, AL139193.1, AL139193.2, AL122020.2, AL122020.1, LINC02321, RPS6KA5, DGLUCY, RNU7-30P, SNORA11B, GPR68, AL135818.1, AL135818.2, CCDC88C, AL133153.2, AL133153.1, PPP4R3A, AL133373.2, AL133373.3, CATSPERB, POLR3GP1, NANOGP7, AL121839.1, U3, AL121839.2, TC2N, FBLN5, TRIP11, AL049872.1, ATXN3.
- chr14:95,876,392–96,793,084, 23 genes, copy number 5: TUNAR, AL137190.1, C14orf132, BDKRB2, AL355102.2, AL355102.1, CKS1BP1, AL355102.5, BDKRB1, AL355102.4, AL355102.3, ATG2B, GSKIP, RNU2-33P, AK7, PEBP1P1, RPL23AP10, AL163051.1, PAPOLA, AL137786.1, RN7SKP108, LINC02299, AL137786.3.
- chr18:11,326,270–12,129,764, 37 genes, copy number 5: AP005139.1, AP005229.1, AP005229.2, AP001109.1, LINC01928, LINC01255, AP001017.1, SLC35G4, AP001120.4, NPIPB1P, AP001120.2, AP001120.3, AP001120.1, GNAL, ASNSP6, AP001120.5, AP005137.1, CHMP1B, CHMP1B-AS1, AP005137.2, MPPE1, AP001269.4, AP001269.2, AP001269.3, IMPA2, AP001269.1, AP001542.3, AP001542.1, AP001542.2, AP002414.1, AP002414.4, AP002414.2, AP002414.5, AP002414.3, ANKRD62, RNU6-324P, SDHDP1.

Autosomal genes at a single copy (total copy number 1): 2,768. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
